Somatic mutation profile of tumor specimen TCGA-AA-3852-01A (aliquot TCGA-AA-3852-01A-01W-0900-09) from TCGA case TCGA-AA-3852, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 88.2 years (32,203 days).
Specimen TCGA-AA-3852-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e470d12-b363-4576-a1ba-b1aec9155f5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3852-10A (Blood Derived Normal), aliquot TCGA-AA-3852-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4194669-6682-44a9-bff1-4ea0652ead3a

The open-access MAF lists 149 somatic variants for this specimen: 116 protein-altering or splice-affecting, 29 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 29, Nonsense Mutation 7, Frame Shift Del 5, Splice Site 4, Frame Shift Ins 3, Splice Region 2, RNA 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F9 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 102/132 reads (77%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.476); catalogued as rs137852249, CM123935, CM940591, COSV54379618; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 84/236 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 22/51 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 30/138 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519929, CM126687, COSV55873676, COSV55913749; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.316G>C p.G106R | Missense Mutation (SNP) | VAF 26/138 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519931, COSV55878215, COSV55881107, COSV55917331; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: drug response / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.4813T>G p.F1605V | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV66065264; called by muse, mutect2, varscan2
- ABCA1 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs141348278; called by muse, mutect2, varscan2
- ABCB5 | c.2801C>T p.A934V (on ENST00000404938 / NM_001163941.2; = p.A489V on NM_178559.6) | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs371459532; called by muse, mutect2, varscan2
- ABCF3 | c.692C>A p.P231Q | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53047664, COSV99491074; called by muse, mutect2, varscan2
- ABCF3 | c.1091T>G p.L364R | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV99491646; called by muse, varscan2
- ADAM12 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 11/253 reads (4%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.007); catalogued as COSV100901395; called by muse, mutect2
- ADAM22 | c.2116T>C p.W706R | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55973992; called by muse, mutect2, varscan2
- ADGRB2 | c.4328G>A p.R1443Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.594); catalogued as rs761734906, COSV57072465; called by muse, varscan2
- ADGRV1 | c.12425G>A p.R4142Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs1047782967, COSV67982871; ClinVar: uncertain significance; called by muse, mutect2
- AHNAK2 | c.7117G>A p.A2373T | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated (0.23); PolyPhen benign (0.292); catalogued as rs200387258; called by muse, mutect2, varscan2
- AIMP2 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 12/103 reads (12%) | catalogued as COSV99552257; called by muse, mutect2, varscan2
- ANK2 | c.3970G>A p.V1324I | Missense Mutation (SNP) | VAF 81/256 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1261943601, COSV52154963; called by muse, mutect2, varscan2
- APC | c.4262del p.S1421Mfs*52 | Frame Shift Del (DEL) | VAF 128/238 reads (54%) | catalogued as COSV57334876, COSV57336346; called by mutect2, pindel, varscan2
- ARAP1 | c.3235C>T p.R1079W (on ENST00000393609 / NM_001040118.2; = p.R834W on NM_015242.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146883151; called by muse, mutect2, varscan2
- ARFGEF1 | c.3268G>T p.E1090* | Nonsense Mutation (SNP) | VAF 62/222 reads (28%) | catalogued as COSV51606021; called by muse, mutect2, varscan2
- ARMC3 | c.1091T>A p.L364* | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | catalogued as COSV53059480; called by muse, mutect2, varscan2
- BRD7 | c.399G>C p.Q133H | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV67158558; called by muse, mutect2, varscan2
- CARD11 | c.3451G>A p.E1151K | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV67797998; called by muse, varscan2
- CDH20 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.055); catalogued as COSV53007836; called by muse, mutect2, varscan2
- CENPC | c.1636G>T p.V546L | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV56622264; called by muse, mutect2, varscan2
- CES3 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs922162797, COSV57593164; called by muse, mutect2, varscan2
- CFH | c.1696+1G>A p.X566_splice | Splice Site (SNP) | VAF 30/109 reads (28%) | catalogued as COSV100810118; called by muse, mutect2, varscan2
- CHD4 | c.2411G>A p.R804Q (on ENST00000357008 / NM_001363606.2; = p.R817Q on NM_001273.5) | Missense Mutation (SNP) | VAF 255/512 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs775293840, COSV58898389; called by muse, varscan2
- CSMD1 | c.9064G>T p.A3022S (on ENST00000520002; = p.A3021S on NM_033225.6) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV59306432; called by muse, mutect2, varscan2
- CSRNP3 | c.10A>G p.I4V | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.163); catalogued as COSV58777122; called by muse, mutect2, varscan2
- CYB5R4 | c.503C>A p.P168Q | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV100859748, COSV63750520; called by muse, mutect2, varscan2
- CYB5R4 | c.504A>C p.P168= | Splice Region (SNP) | VAF 39/111 reads (35%) | catalogued as COSV100859749, COSV63751558; called by muse, mutect2, varscan2
- DDX17 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 69/152 reads (45%) | catalogued as COSV53251782; called by muse, mutect2, varscan2
- EDEM2 | c.1376C>A p.T459N | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.841); catalogued as rs746259676, COSV63259485; called by muse, mutect2, varscan2
- ESRP1 | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV64408849; called by muse, mutect2, varscan2
- FN1 | c.5977G>A p.E1993K | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.717); catalogued as rs775650652, COSV100117886, COSV60550006; called by muse, mutect2, varscan2
- FNBP1 | c.1363G>T p.D455Y | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV63086365; called by muse, mutect2, varscan2
- GRIK3 | c.2701C>T p.R901W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs757906633, COSV66138026; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1870C>T p.R624W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV56085832; called by muse, mutect2
- GZF1 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57635636; called by muse, mutect2, varscan2
- HDLBP | c.268A>G p.K90E | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); catalogued as COSV60494238; called by muse, mutect2, varscan2
- ITIH6 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV99513909; called by muse, mutect2
- KARS1 | c.504A>T p.E168D | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV56691597; called by muse, mutect2, varscan2
- KATNIP | c.1133C>A p.A378E | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.368); catalogued as COSV55177978; called by muse, mutect2, varscan2
- LVRN | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.838); catalogued as COSV63496963; called by muse, mutect2, varscan2
- MAP2 | c.2596G>T p.D866Y | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52287051; called by muse, mutect2, varscan2
- MAP3K15 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as rs143201437, COSV100134525, COSV58828196; called by muse, mutect2, varscan2
- MARVELD2 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs770606860, COSV57780216; called by muse, mutect2, varscan2
- MED1 | c.1592C>T p.T531I | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56123606; called by muse, mutect2, varscan2
- MXD1 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV52479536; called by muse, mutect2, varscan2
- MYCBP2 | c.10283A>G p.D3428G (on ENST00000357337; = p.D3466G on NM_015057.5) | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV62014945; called by muse, mutect2, varscan2
- NDST4 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 82/267 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.251); catalogued as rs1406104906, COSV52115083; called by muse, mutect2, varscan2
- NELL1 | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54253261; called by muse, mutect2, varscan2
- NQO1 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs114112422, COSV57731309; called by muse, mutect2, varscan2
- NR0B1 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 63/85 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1261361082, COSV66763907; called by muse, mutect2, varscan2
- NUMA1 | c.2948G>A p.R983Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs761219488, COSV61184022; called by muse, mutect2, varscan2
- NWD1 | c.1744G>A p.V582M | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as rs143795871; called by muse, mutect2, varscan2
- OR51V1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.177); catalogued as rs368941887; called by muse, mutect2, varscan2
- OR52N1 | c.184T>C p.Y62H | Missense Mutation (SNP) | VAF 59/212 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs1386866446, COSV57693161; called by muse, mutect2, varscan2
- PCDHA1 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs1554118039, COSV65374686; called by muse, mutect2
- PDGFRB | c.760-1G>A p.X254_splice | Splice Site (SNP) | VAF 6/31 reads (19%) | catalogued as COSV55802238; called by muse, mutect2
- PIP4K2B | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1428783424; called by muse, mutect2, varscan2
- PLA2G4C | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775130071, COSV100844038; called by muse, mutect2, varscan2
- PLEKHG1 | c.3088G>A p.A1030T | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745737557, COSV62046507; called by muse, mutect2, varscan2
- PM20D2 | c.725G>C p.R242T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51530195; called by muse, mutect2, varscan2
- PPIP5K2 | c.3145G>A p.E1049K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as rs140891481; called by muse, mutect2, varscan2
- PPL | c.3802G>A p.E1268K | Missense Mutation (SNP) | VAF 95/268 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52167296; called by muse, mutect2, varscan2
- PPP1R3A | c.2587G>T p.D863Y | Missense Mutation (SNP) | VAF 159/543 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as COSV52880177, COSV52894860; called by muse, mutect2, varscan2
- PRAMEF4 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 293/957 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs562920609, COSV52437653; called by muse, mutect2, varscan2
- PRB4 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 27/962 reads (3%) | catalogued as rs747416505; called by muse, mutect2
- PRKCB | c.1619C>A p.P540H | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57773941; called by muse, mutect2, varscan2
- PRSS58 | c.344A>G p.D115G | Missense Mutation (SNP) | VAF 156/328 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.253); catalogued as COSV73488523; called by muse, mutect2, varscan2
- PSMD14 | c.570G>A p.Q190= | Splice Region (SNP) | VAF 15/34 reads (44%) | catalogued as COSV68832135; called by muse, mutect2, varscan2
- PTPRM | c.1684A>T p.T562S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as COSV59843661, COSV59853132; called by muse, mutect2, varscan2
- REP15 | c.337_338del p.L113Afs*11 | Frame Shift Del (DEL) | VAF 40/232 reads (17%) | catalogued as rs781175571; called by pindel, varscan2
- RNF111 | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | catalogued as COSV62084267, COSV62087885; called by muse, mutect2, varscan2
- ROBO2 | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.87); catalogued as rs201678507, CM084999, COSV59905570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RUFY4 | c.905C>A p.A302D | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.582); catalogued as COSV60246881; called by muse, mutect2, varscan2
- SENP3 | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99547978; called by muse, mutect2, varscan2
- SH3GLB1 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.042); catalogued as COSV65279516; called by muse, mutect2, varscan2
- SLC17A8 | c.1352G>T p.G451V | Missense Mutation (SNP) | VAF 177/358 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60123154; called by muse, mutect2, varscan2
- SLC1A2 | c.1474A>T p.I492L | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV53520112; called by muse, mutect2, varscan2
- SLC6A11 | c.1357G>A p.V453M | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.689); catalogued as rs548624556, COSV54392114; called by muse, mutect2, varscan2
- STAT5A | c.990-1G>T p.X330_splice | Splice Site (SNP) | VAF 24/67 reads (36%) | catalogued as COSV61806348, COSV61808404; called by muse, mutect2, varscan2
- SUPT7L | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs372248888; called by muse, mutect2, varscan2
- SYNE1 | c.10288G>A p.G3430R (on ENST00000367255 / NM_182961.4; = p.G3437R on NM_033071.3) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as rs1047722501, COSV54952483; called by muse, mutect2, varscan2
- SYNJ2BP | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as COSV56445340; called by muse, mutect2
- TCF4 | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100610788; called by muse, mutect2
- TENM2 | c.4849T>A p.F1617I (on ENST00000518659 / NM_001122679.2; = p.F1378I on NM_001080428.3) | Missense Mutation (SNP) | VAF 114/273 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV69127325; called by muse, mutect2, varscan2
- TEX47 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 50/300 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51878631; called by muse, varscan2
- TLE1 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV64720325; called by muse, mutect2, varscan2
- TM4SF4 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs188249785; called by muse, mutect2, varscan2
- TMPRSS11F | c.553+1G>A p.X185_splice | Splice Site (SNP) | VAF 39/126 reads (31%) | catalogued as rs200354776, COSV62465842; called by muse, mutect2, varscan2
- TNXB | c.6551C>T p.S2184F (on ENST00000647633; = p.S1937F on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as rs535547075, COSV100926604; called by muse, mutect2
- TOR1AIP1 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as rs748833315, COSV54868111, COSV54869078; called by muse, mutect2, varscan2
- TRPC7 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs770873060, COSV61456484; called by muse, varscan2
- TSPAN3 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as rs1480834474, COSV51214781; called by muse, mutect2, varscan2
- TTBK1 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.302); catalogued as rs771750279, COSV52488754; called by muse, mutect2, varscan2
- UBE2L3 | c.143A>C p.K48T | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV60536190, COSV60536506; called by muse, mutect2, varscan2
- UGP2 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1351745580, COSV61427862; called by muse, mutect2, varscan2
- USP10 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1166998938, COSV54748161; called by muse, mutect2, varscan2
- USP33 | c.463A>G p.N155D | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV62468934; called by muse, mutect2, varscan2
- YTHDF3 | c.569G>A p.G190D | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as COSV72773415; called by muse, mutect2, varscan2
- ZBTB7C | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.768); catalogued as rs774550186, COSV59688255; called by muse, mutect2, varscan2
- ZEB1 | c.2179C>A p.Q727K | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.078); catalogued as COSV58041358; called by muse, mutect2, varscan2
- ZNF337 | c.1550dup p.C518Lfs*33 | Frame Shift Ins (INS) | VAF 81/290 reads (28%) | catalogued as rs767883564; called by mutect2, pindel, varscan2
- ZNF404 | c.1363A>T p.I455F | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.452); catalogued as COSV60986886; called by muse, mutect2, varscan2
- ZNF804B | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV60823219; called by muse, mutect2, varscan2
- ZRANB1 | c.383G>C p.R128T | Missense Mutation (SNP) | VAF 79/268 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as rs1260156291, COSV62842019; called by muse, mutect2, varscan2
- ZSCAN20 | c.2357G>T p.R786I | Missense Mutation (SNP) | VAF 143/536 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1419692053, COSV63682136, COSV63682306; called by muse, mutect2, varscan2
- CNTNAP4 | c.3068del p.N1023Tfs*13 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | called by mutect2, pindel, varscan2
- PLD1 | c.880_886del p.K294Efs*13 | Frame Shift Del (DEL) | VAF 61/276 reads (22%) | called by mutect2, pindel, varscan2
- SIPA1L1 | c.2180dup p.N727Kfs*21 | Frame Shift Ins (INS) | VAF 78/142 reads (55%) | called by mutect2, pindel, varscan2
- SUPT16H | c.2291_2292del p.Y764Cfs*2 | Frame Shift Del (DEL) | VAF 42/142 reads (30%) | called by mutect2, pindel, varscan2
- UNC13C | c.5151dup p.D1718Rfs*8 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- ASH1L | c.7848G>T p.V2616= (on ENST00000368346 / NM_001366177.2; = p.V2611= on NM_018489.3) | Silent (SNP) | VAF 79/206 reads (38%) | catalogued as COSV64206922; called by muse, mutect2, varscan2
- FAM149A | c.2160G>A p.T720= (on ENST00000356371 / NM_001367768.2; = p.T429= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as rs145714089; called by muse, mutect2, varscan2
- FBLN7 | c.870C>T p.T290= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs370641244; called by muse, mutect2, varscan2
- FRG2C | c.771A>G p.R257= | Silent (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- GALC | c.1392C>T p.F464= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV54325744; called by muse, mutect2
- GBP1 | c.1047C>A p.T349= | Silent (SNP) | VAF 57/133 reads (43%) | catalogued as COSV65083188; called by muse, mutect2, varscan2
- GDF6 | c.273C>T p.R91= | Silent (SNP) | VAF 60/98 reads (61%) | catalogued as COSV54622739; called by muse, mutect2, varscan2
- ITGA2 | c.54G>T p.A18= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV56858433; called by muse, mutect2, varscan2
- IZUMO1R | c.405C>T p.D135= (on ENST00000440961; = p.D142= on NM_001199206.3) | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs778163552, COSV60622506; called by muse, mutect2, varscan2
- KRT25 | c.1017G>A p.A339= | Silent (SNP) | VAF 111/245 reads (45%) | catalogued as rs753281617, COSV56443647; called by muse, mutect2, varscan2
- LDB3 | c.2049C>T p.I683= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as rs377178682; called by muse, mutect2, varscan2
- LRRC8D | c.1407G>A p.Q469= | Silent (SNP) | VAF 52/116 reads (45%) | catalogued as rs371125847, COSV61579166; called by muse, mutect2, varscan2
- MED10 | c.354G>A p.P118= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs151062073; called by muse, mutect2, varscan2
- MFN2 | c.480G>A p.V160= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV99337033; called by muse, mutect2
- MMRN2 | c.1503G>A p.L501= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100922652, COSV64400806; called by muse, mutect2
- MYOM2 | c.537A>G p.G179= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs779498611, COSV100038299; called by muse, mutect2, varscan2
- PXDN | c.2340C>A p.G780= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV53230716, COSV53231025; called by muse, mutect2, varscan2
- RFLNB | c.150C>T p.D50= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs1280117741, COSV61239210; called by muse, mutect2, varscan2
- RYR3 | c.4857G>A p.K1619= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV66783868; called by muse, mutect2, varscan2
- SLC32A1 | c.381C>T p.N127= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV54146268; called by muse, mutect2, varscan2
- SLITRK5 | c.1782G>A p.A594= | Silent (SNP) | VAF 66/150 reads (44%) | catalogued as COSV61522055; called by muse, mutect2, varscan2
- SPECC1 | c.1704C>T p.A568= | Silent (SNP) | VAF 32/127 reads (25%) | catalogued as COSV54955979; called by muse, mutect2, varscan2
- TAS1R2 | c.1041G>A p.P347= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs377629361, COSV64744362; called by muse, mutect2
- TBATA | c.960C>T p.S320= | Silent (SNP) | VAF 53/152 reads (35%) | catalogued as rs749992519, COSV54718268; called by muse, mutect2, varscan2
- TERF2IP | c.978C>T p.N326= | Silent (SNP) | VAF 11/250 reads (4%) | catalogued as rs1187298566, COSV100265692; called by muse, mutect2
- TMEM143 | c.177C>T p.N59= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV53155972; called by muse, mutect2, varscan2
- TRIM67 | c.1743C>T p.Y581= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV64158584; called by muse, mutect2, varscan2
- ZFP28 | c.921C>T p.T307= | Silent (SNP) | VAF 50/124 reads (40%) | catalogued as COSV56735390; called by muse, mutect2, varscan2
- ZNF423 | c.2808C>A p.G936= (on ENST00000563137 / NM_001379286.1; = p.G928= on NM_015069.4) | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV52183985; called by muse, mutect2, varscan2
- OFCC1 | n.243C>T | RNA (SNP) | VAF 67/180 reads (37%) | catalogued as rs540758750; called by muse, mutect2, varscan2
- STK4 | c.1306-21907G>A | Intron (SNP) | VAF 35/105 reads (33%) | catalogued as COSV100860446; called by muse, mutect2, varscan2
- TCP10L3 | n.2719+1182A>G | Intron (SNP) | VAF 11/46 reads (24%) | catalogued as COSV64750417; called by muse, mutect2
- XIST | n.9784C>T | RNA (SNP) | VAF 17/25 reads (68%) | catalogued as rs779975432; called by muse, mutect2, varscan2
